Somatic mutation profile of tumor specimen TARGET-10-PAPDKR-09A (aliquot TARGET-10-PAPDKR-09A-01D) from TARGET case TARGET-10-PAPDKR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (636 days).
Specimen TARGET-10-PAPDKR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12de55a0-491a-4b30-8b0e-beab01bb2d73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDKR-10A (Blood Derived Normal), aliquot TARGET-10-PAPDKR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5c7603e-be7b-48bb-a97b-d37bf86b5332

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STMN2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as COSV55220490; called by muse, mutect2, varscan2
- AMOT | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COL4A5 | c.1820A>T p.N607I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.089); called by muse, mutect2
- OR56B4 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PCDHA2 | c.1785C>T p.R595= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1554120080; called by muse, mutect2, varscan2
- RHCG | c.1299G>A p.A433= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs546926679; called by muse, mutect2, varscan2
- GPS1 | c.*341G>A | 3'UTR (SNP) | VAF 13/43 reads (30%) | catalogued as rs778300415; called by muse, mutect2, varscan2
